Somatic mutation profile of tumor specimen TCGA-JX-A5QV-01A (aliquot TCGA-JX-A5QV-01A-22D-A28B-09) from TCGA case TCGA-JX-A5QV, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 37.4 years (13,667 days).
Specimen TCGA-JX-A5QV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78664cc1-e35d-4147-ac42-3bfcad801c18.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-JX-A5QV-10A (Blood Derived Normal), aliquot TCGA-JX-A5QV-10A-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75fc1b7e-37cd-4c18-adcd-744e62449cd5

The open-access MAF lists 53 somatic variants for this specimen: 35 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 17, Frame Shift Del 2, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AEBP2 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56863443; called by muse, mutect2, varscan2
- ANO1 | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as rs768459625, COSV100303875; called by mutect2, varscan2
- C10orf62 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs754404049, COSV65705224; called by muse, mutect2, varscan2
- CDH7 | c.2084G>A p.R695Q | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.598); catalogued as COSV59886164; called by muse, mutect2, varscan2
- CEP112 | c.2308G>A p.V770I | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs137923595; called by muse, mutect2, varscan2
- CFHR3 | c.396A>T p.K132N | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1201872363, COSV66402162; called by muse, mutect2, varscan2
- CPA1 | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV50569686; called by muse, mutect2, varscan2
- CTNND2 | c.1948G>C p.D650H | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58888242, COSV58889653; called by muse, mutect2, varscan2
- EHD4 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55004780, COSV99587745; called by muse, mutect2, varscan2
- FCRL3 | c.1126G>A p.V376M | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs770508420, COSV100943065; called by muse, mutect2, varscan2
- GIPR | c.179C>A p.A60D | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as COSV54423975, COSV54424544; called by muse, mutect2, varscan2
- HIF3A | c.214G>A p.A72T (on ENST00000377670 / NM_152795.4; = p.P51= on NM_022462.4) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.072); catalogued as COSV52198318; called by muse, mutect2
- HSP90AA1 | c.394G>C p.G132R | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99355183; called by muse, mutect2
- IQGAP1 | c.1376C>T p.S459L | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs546591604, COSV51585519; called by muse, mutect2, varscan2
- MAPKAPK2 | c.880G>A p.V294I | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.644); catalogued as COSV54315991; called by muse, mutect2, varscan2
- MICAL1 | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as rs137916380, COSV57805254; called by muse, mutect2, varscan2
- P2RY4 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 76/156 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as COSV65736661; called by muse, mutect2, varscan2
- PCDHB13 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.812); catalogued as rs1212390195, COSV53396493; called by muse, mutect2, varscan2
- PCED1B | c.190G>C p.G64R | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71395199; called by muse, mutect2
- PIK3AP1 | c.1099G>A p.V367M | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs564621240, COSV59532420; called by muse, mutect2, varscan2
- QSOX2 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 70/137 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as rs368735255; called by muse, mutect2, varscan2
- RAPGEF1 | c.1189C>T p.L397F | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV64699524; called by muse, mutect2
- SERBP1 | c.946G>A p.D316N (on ENST00000370995 / NM_001018067.2; = p.D295N on NM_015640.4) | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.145); catalogued as COSV63413501; called by muse, mutect2, varscan2
- SFSWAP | c.1411G>A p.G471S | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776310309, COSV55521928; called by muse, mutect2, varscan2
- TMEM143 | c.1294C>T p.P432S | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53156477; called by muse, mutect2, varscan2
- TMEM94 | c.2671G>A p.E891K | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs1251201218, COSV58595548; called by muse, mutect2, varscan2
- TRA2B | c.650G>T p.R217L | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99373235; called by muse, mutect2
- TRGV9 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs372923357; called by muse, mutect2, varscan2
- TTLL6 | c.2454C>A p.S818R (on ENST00000393382 / NM_001130918.3; = p.S511R on NM_173623.3) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as rs1169354499, COSV64977197; called by muse, mutect2
- UBQLN2 | c.295C>T p.H99Y | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV57739574; called by muse, mutect2, varscan2
- ZC3H13 | c.2041C>G p.R681G | Missense Mutation (SNP) | VAF 69/274 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.68); catalogued as COSV54453504, COSV54458914; called by muse, mutect2, varscan2
- ZNF318 | c.3347G>A p.R1116H | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs776514732, COSV58932538; called by muse, varscan2
- ZNF804B | c.2614C>T p.Q872* | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as COSV60827610, COSV60831178; called by muse, mutect2, varscan2
- ATF6 | c.7del p.E3? | Frame Shift Del (DEL) | VAF 7/70 reads (10%) | called by mutect2, pindel, varscan2
- TTYH1 | c.1165_1174del p.L389Cfs*85 | Frame Shift Del (DEL) | VAF 10/99 reads (10%) | called by mutect2, pindel
- A2M | c.372C>T p.N124= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as rs199872729, COSV100588556, COSV59383658; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2259C>T p.C753= | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as rs956330703; called by muse, mutect2, varscan2
- BCORL1 | c.4443C>T p.N1481= | Silent (SNP) | VAF 56/108 reads (52%) | catalogued as rs145380229, COSV54396132; called by muse, mutect2, varscan2
- BDKRB2 | c.459C>T p.I153= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as rs775508034, COSV60014825; called by muse, mutect2, varscan2
- HROB | c.1633C>T p.L545= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV55369611; called by mutect2, varscan2
- NEUROD1 | c.357G>A p.A119= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as rs375774931, COSV99716753; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRP1 | c.324C>T p.A108= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs769188345, COSV55166747; called by muse, mutect2, varscan2
- OGDHL | c.198C>A p.V66= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV65102355; called by muse, mutect2, varscan2
- P2RX7 | c.1476G>A p.R492= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV55855135; called by muse, mutect2, varscan2
- PCCB | c.555G>A p.T185= | Silent (SNP) | VAF 60/134 reads (45%) | catalogued as rs543691110, COSV99291209; ClinVar: likely benign; called by muse, mutect2, varscan2
- PDZD4 | c.1135C>A p.R379= | Silent (SNP) | VAF 41/71 reads (58%) | catalogued as COSV51246754; called by muse, mutect2, varscan2
- PDZRN3 | c.2976C>T p.R992= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV99728803; called by muse, mutect2, varscan2
- PIGR | c.219C>T p.Y73= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as rs766615344, COSV62904009; called by muse, mutect2, varscan2
- RYR3 | c.10752C>T p.A3584= (on ENST00000389232; = p.A3585= on NM_001036.6) | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV66788833; called by muse, varscan2
- SLC28A2 | c.1140G>A p.A380= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as rs17215626; called by muse, mutect2, varscan2
- SLC6A15 | c.1317C>T p.T439= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs140083416; called by muse, mutect2, varscan2
- SLFN5 | c.2499G>A p.S833= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs762718475, COSV55481160; called by muse, mutect2, varscan2
- SNX18 | c.1774+59G>T | Intron (SNP) | VAF 10/55 reads (18%) | catalogued as COSV57989228; called by muse, mutect2, varscan2
